Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3685, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3685-01A (Primary Tumor).

Diagnosis:

Colon resection material includes a moderately differentiated colorectal type of adenocarcinoma, max. 3.8 cm in size, with infiltration of the pericolic fatty tissue and focal evidence of carcinomatous lymphangiosis. Tumor-free regional lymph nodes. Tumor-free colon resection margins. Tumor-free mesenteric resection margin

Tumor stage: pT3 pN0 (0/24) pMX; G2 L1 V0 R0

Source: NCI Genomic Data Commons file 80db4b2a-a834-4444-ac18-dfde0f5aa1d5 (TCGA-AA-3685.26CC9EA1-5415-4FBB-958C-F9FC005BF8E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).